Surgical pathology report (de-identified scan), TCGA case TCGA-A4-A57E, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-A57E-01A (Primary Tumor).

[page 1 of 3]
SEX: Male
D.O.B.:
MRN #:
Ref Phy

SPECIMEN INFORMATION

Collected:
Received:
Reported:

Accession #:
#:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Left kidney and adrenal gland:

Tumor Characteristics:

1. Histologic type: Renal cell carcinoma, mixed type (chromophobe, papillary, clear cell). *TLGA sample is 100% papillary, per TSS.*
2. Tumor site: Upper lobe of left kidney.
3. Tumor focality: Unifocal. *12/4/12*
4. Tumor size: 7.5 x 6.0 x 5.8 cm.
5. Macroscopic extent of tumor: Neoplasm appears to be confined to the contents of the kidney.
6. Microscopic extent of tumor: Neoplasm does not appear to invade through the renal capsule.
7. Nuclear grade: Fuhrman grade 3/4.
8. Lymphovascular space invasion: No.
9. Sarcomatoid features: Absent.

Surgical Margin Status:

1. Margins are uninvolved by carcinoma.
2. Ureteral margin: Negative.
3. Soft tissue margins: Negative.
4. Vascular margins: Negative.

Lymph Node Status:

1. Total number of lymph nodes received: 1 (hilar).
2. Total number of lymph nodes containing metastatic carcinoma: 0.

Other:

1. Other significant findings: Adrenal gland: Metastatic renal cell carcinoma. (see comment)
- Chronic pyelonephritis.
2. pTNM stage: T2a N0 M1.

ICD-O-3

Carcinoma, papillary, renal cell
8260/3

Site: @ Kidney, NOS
C64.9
QD 12/5/12

Electronic signature.

COMMENTS:

Sections of the adrenal gland demonstrate adrenal cortical hyperplasia with extensive hemorrhage and focal necrosis within the medullary component. A single nodule of clear cell proliferation which is well vascularized is noted and because of the histologic features immunohistochemical stains are performed with the following results:

RCC: Positive.
CD10: Positive.
Vimentin: Positive.

Based on the immunohistochemical results and the H&E findings the features of the adrenal nodule are most consistent with those of metastatic renal cell carcinoma.

This case has been reviewed in intradepartmental consultation and as part of the Department's Quality Review Program by _____ in agreement with the diagnosis.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Abdominal mass unspecified site.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Left kidney and adrenal gland.

[page 2 of 3]
GROSS DESCRIPTION:

The specimen is received labeled _____ kidney and adrenal gland. The specimen consists of a kidney with attached perinephric fat that measures 20 x 14 x 10 cm., weighs 1,045 grams. There is a portion of adrenal gland attached to the specimen as well as a detached piece of an adrenal gland within the container. The adrenal gland together measures 4.5 x 2 x 2 cm. The cut surface is golden yellow with areas of hemorrhage. The ureter measures 9.5 cm. in length, 0.3 cm. in diameter. The surface is gray to brown-tan. The ureter is opened. The mucosal surface is light tan. There is no material within the lumen or lesions identified. The renal artery measures 1.5 cm. in length, 0.5 cm. in diameter. It is grossly unremarkable. The renal vein measures 1.5 cm. in diameter. Sectioning there is tumor visible within the lumen, it is 0.6 cm. from the resected margin.

At the hilum there is a yellow-tan nodule measuring 1 x 1 x 0.5 cm. possible lymph node. The soft tissue resection margin is yellow-tan slightly shaggy. The resected margin has been inked. The kidney is bisected and reveals a yellow to brown-tan variegated soft friable shaggy mass measuring 7.5 x 6 x 5.8 cm. within the upper pole that on sectioning is grossly confined to the capsule and does not show evidence of invasion into the perinephric fat. It comes within 0.1 cm. of the inked resected margin. The mass does not involve the surrounding renal calices pelvis. The calices, pelvis are gray-tan. The surrounding renal cortex is brown-tan and measures 0.5 cm. and shows a well demarcated corticomedullary junction. No other lesions are identified grossly.

Received with the specimen are three cassettes - one green, one yellow, one blue labeled 16. The green cassette additionally labeled - 17; and the blue cassette additionally labeled - 18.

with the yellow cassette additionally labeled -

Representative sections are submitted in cassettes labeled _____ follows: sections from mass in blocks 1 through 4; ureter block 5; renal artery and vein in block 6; surrounding uninvolved kidney in block 7; possible hilar lymph node bisected in block 8; adrenal gland in block 9.

H/2AA Discrepancy		X

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.001

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: A4 TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____

Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Renal Cell Carcinoma, Mixed type (chromophobe, papillary, clear cell)	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Papillary Renal Cell Carcinoma * Annotation: Per path. review the sample submitted is 100% papillary renal carcinoma.	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Only one slide is reviewed which appears to show with some frozen section artifact a papillary carcinoma. However, other slides reviewed by the diagnosing pathologist may have shown a chromophobe or clear cell component. In addition, special stains may have been performed to support this diagnosis, which I do not have the benefit of reviewing.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	I do not have the benefit of reviewing.	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing

Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 242e18ca-a8ce-4767-b51b-fa5f6af8c0ed (TCGA-A4-A57E.5F310E76-71F2-4E9E-83D1-85B05BDB501B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).